Somatic mutation profile of tumor specimen ALCH-B24O-TTP1-A (aliquot ALCH-B24O-TTP1-A-3-0-D-A773-36) from ALCHEMIST case ALCH-B24O, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 43.2 years (15,790 days).
Specimen ALCH-B24O-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb83651e-7334-40d0-bbdb-0e9feec2b2bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B24O-NB1-A (Blood Derived Normal), aliquot ALCH-B24O-NB1-A-1-0-D-A773-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03369b2b-45d3-4393-99fb-32a097cf71e2

The open-access MAF lists 362 somatic variants for this specimen: 247 protein-altering or splice-affecting, 58 silent, 57 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 202, Silent 58, Nonsense Mutation 24, Intron 23, RNA 14, Splice Site 10, 3'UTR 9, 5'UTR 6, 5'Flank 5, Frame Shift Del 4, Translation Start Site 3, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.740A>T p.N247I | Missense Mutation (SNP) | VAF 50/404 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786201762, COSV52675458, COSV52732730, COSV53026017; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- ADGRB1 | c.1808G>C p.R603P | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV60098123; called by muse, mutect2, varscan2
- AKAP12 | c.3310G>C p.E1104Q | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as COSV53572438; called by muse, mutect2
- AL592490.1 | c.2476G>T p.D826Y | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99082097; called by muse, mutect2, varscan2
- ANK3 | c.1565G>T p.G522V | Missense Mutation (SNP) | VAF 59/509 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99781457; called by muse, mutect2, varscan2
- ANKRD30B | c.2563C>A p.Q855K | Missense Mutation (SNP) | VAF 22/236 reads (9%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.106); catalogued as COSV57703646; called by muse, mutect2, varscan2
- BAIAP3 | c.1173G>T p.R391S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); catalogued as COSV60979386; called by muse, mutect2
- CDH9 | c.1370C>A p.T457N | Missense Mutation (SNP) | VAF 14/165 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV50284425; called by muse, mutect2
- CEACAM3 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 34/378 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs146460004; called by muse, mutect2
- CEACAM3 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 34/377 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55761896; called by muse, mutect2
- COL22A1 | c.2189C>G p.S730C | Missense Mutation (SNP) | VAF 78/343 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV57328424, COSV57348084; called by muse, varscan2
- COL25A1 | c.1711-1G>T p.X571_splice | Splice Site (SNP) | VAF 22/286 reads (8%) | catalogued as COSV101210993; called by muse, mutect2
- CWH43 | c.665G>T p.W222L | Missense Mutation (SNP) | VAF 25/239 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV56940502; called by muse, mutect2, varscan2
- CXCR6 | c.944C>A p.S315* | Nonsense Mutation (SNP) | VAF 59/297 reads (20%) | catalogued as COSV99945404; called by muse, mutect2, varscan2
- DACH2 | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 24/188 reads (13%) | catalogued as COSV100914143; called by muse, mutect2, varscan2
- DAPP1 | c.193G>T p.E65* | Nonsense Mutation (SNP) | VAF 25/315 reads (8%) | catalogued as COSV56453463; called by muse, mutect2
- DENND2A | c.2641G>T p.E881* | Nonsense Mutation (SNP) | VAF 91/280 reads (33%) | catalogued as COSV99325724; called by muse, mutect2, varscan2
- DNAH11 | c.5806G>T p.V1936L | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs369757206; called by muse, mutect2
- DNAH2 | c.4292G>T p.R1431L | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as rs780075239; called by muse, mutect2
- DPP6 | c.2260G>T p.E754* (on ENST00000377770 / NM_001364500.2; = p.E692* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 29/428 reads (7%) | catalogued as COSV59624369; called by muse, mutect2
- EPHA7 | c.2756C>G p.T919S | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.296); catalogued as COSV100993372; called by muse, mutect2, varscan2
- FAT4 | c.4579C>A p.P1527T | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67902374; called by muse, mutect2, varscan2
- FLG | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 73/699 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV64239357; called by muse, mutect2, varscan2
- FMN2 | c.2397C>G p.D799E | Missense Mutation (SNP) | VAF 55/373 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.062); catalogued as COSV60442889; called by muse, mutect2, varscan2
- FMR1 | c.707C>G p.T236S | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.105); catalogued as rs1426866986, COSV54427348; called by muse, mutect2
- FREM3 | c.1108C>A p.L370I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.419); catalogued as rs757376490; called by muse, mutect2, varscan2
- FRMPD3 | c.1487T>C p.M496T | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT tolerated (0.78); PolyPhen benign (0.047); catalogued as rs761550922; called by muse, mutect2
- GALNT17 | c.1694C>A p.T565K | Missense Mutation (SNP) | VAF 41/398 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61186018, COSV61195738; called by muse, mutect2, varscan2
- GLI3 | c.2092G>T p.E698* | Nonsense Mutation (SNP) | VAF 14/246 reads (6%) | catalogued as COSV67891889; called by muse, mutect2
- GPR158 | c.1574G>T p.R525L | Missense Mutation (SNP) | VAF 49/431 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66275191; called by muse, mutect2, varscan2
- HDAC9 | c.3085C>T p.Q1029* (on ENST00000441542 / NM_178425.3; = p.Q1026* on NM_178423.3) | Nonsense Mutation (SNP) | VAF 15/352 reads (4%) | catalogued as COSV67770625; called by muse, mutect2
- INPP4B | c.2486C>A p.T829K | Missense Mutation (SNP) | VAF 40/618 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.303); catalogued as COSV53710452, COSV53738323; called by muse, mutect2
- KIF4B | c.3169G>T p.D1057Y | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV70529486; called by muse, varscan2
- LGI1 | c.432G>A p.L144= | Splice Region (SNP) | VAF 86/906 reads (9%) | catalogued as rs920223409, COSV65059205; called by muse, mutect2
- MAP4K3 | c.424A>G p.I142V | Missense Mutation (SNP) | VAF 21/311 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs1176717891; called by muse, mutect2
- MPHOSPH10 | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as rs1185357855; called by muse, mutect2, varscan2
- MUC2 | c.2656G>T p.V886F | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.27); catalogued as rs753335587; called by muse, mutect2
- MYH4 | c.939C>A p.F313L | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV55116528; called by muse, mutect2, varscan2
- NAALAD2 | c.356C>A p.S119* | Nonsense Mutation (SNP) | VAF 12/83 reads (14%) | catalogued as rs760348318, COSV58959565; called by muse, mutect2, varscan2
- NCKAP1 | c.1588G>T p.V530L | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV100720569; called by muse, mutect2, varscan2
- NLRP3 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 28/301 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60226409, COSV60228660; called by muse, mutect2
- NOD2 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1263235006; called by muse, mutect2, varscan2
- NOS1 | c.343G>T p.G115W | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV57613152; called by muse, mutect2
- NTRK3 | c.2428G>T p.E810* (on ENST00000360948 / NM_001012338.2; = p.E796* on NM_002530.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/216 reads (6%) | catalogued as COSV62296439, COSV62299492; called by muse, mutect2
- OR2L2 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63555068; called by muse, mutect2, varscan2
- OR2T2 | c.322C>A p.L108M | Missense Mutation (SNP) | VAF 46/906 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.051); catalogued as COSV100737810; called by muse, mutect2
- OR2W3 | c.359A>T p.Y120F | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.165); catalogued as COSV64457794; called by muse, mutect2
- OR5W2 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV60615657; called by muse, mutect2
- OR6K3 | c.689C>A p.A230D (on ENST00000368146; = p.A214D on NM_001005327.2) | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.487); catalogued as rs775479737, COSV63745725; called by muse, mutect2, varscan2
- P2RY4 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 27/276 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100996951; called by muse, mutect2, varscan2
- P3H3 | c.1880C>A p.T627K | Missense Mutation (SNP) | VAF 22/281 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782260834; called by muse, mutect2
- PALD1 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV54974150; called by muse, mutect2, varscan2
- PCDH11X | c.2589G>T p.Q863H | Missense Mutation (SNP) | VAF 46/601 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV53469894; called by muse, mutect2
- PCDHA12 | c.1612C>A p.R538S | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); catalogued as COSV56542763; called by muse, mutect2, varscan2
- PDGFRA | c.2069G>A p.R690K | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT tolerated (1); PolyPhen possibly damaging (0.724); catalogued as COSV99957863; called by muse, varscan2
- POLG | c.3197C>T p.T1066M | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs750794449; ClinVar: uncertain significance; called by muse, mutect2
- PPP1R3F | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as COSV99278741; called by muse, mutect2
- PROSER1 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 38/310 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.621); catalogued as rs1423647125; called by muse, mutect2
- PTPRZ1 | c.1146G>T p.M382I | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as COSV66434229; called by muse, mutect2, varscan2
- PXDNL | c.3403G>T p.V1135L | Missense Mutation (SNP) | VAF 54/304 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777627469; called by muse, varscan2
- RBFOX1 | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV60951341; called by muse, mutect2
- ROBO2 | c.3637G>T p.E1213* | Nonsense Mutation (SNP) | VAF 29/248 reads (12%) | catalogued as COSV100166736, COSV59937523; called by muse, mutect2, varscan2
- RP1L1 | c.3794G>A p.R1265Q | Missense Mutation (SNP) | VAF 50/454 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756233501, COSV66752576; called by muse, varscan2
- SERPINB12 | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as COSV54033799; called by muse, mutect2, varscan2
- SH3KBP1 | c.591C>A p.N197K | Missense Mutation (SNP) | VAF 48/649 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as COSV101114807; called by muse, mutect2
- SH3RF2 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182882077; called by muse, mutect2
- SHISA9 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101428435; called by muse, mutect2
- SLC4A10 | c.1116C>A p.F372L (on ENST00000446997 / NM_001354461.2; = p.F342L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55762649, COSV55802025; called by muse, mutect2
- STK11 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 19/174 reads (11%) | catalogued as HM080026, COSV58826710; called by muse, mutect2, varscan2
- TEX11 | c.245C>A p.T82N (on ENST00000344304; = p.T67N on NM_031276.3) | Missense Mutation (SNP) | VAF 30/368 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV60233158, COSV60239603; called by muse, mutect2
- UNC5C | c.305A>T p.Q102L | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV71662499; called by muse, mutect2
- USH2A | c.1900G>T p.A634S | Missense Mutation (SNP) | VAF 76/499 reads (15%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.817); catalogued as rs759589036, COSV100245191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP11 | c.499G>T p.V167F (on ENST00000218348; = p.V124F on NM_001371072.1) | Missense Mutation (SNP) | VAF 21/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV54475236; called by muse, mutect2
- USP25 | c.857+1G>A p.X286_splice | Splice Site (SNP) | VAF 21/244 reads (9%) | catalogued as rs750113422, COSV53480444; called by muse, mutect2
- USP34 | c.8594C>T p.S2865F | Missense Mutation (SNP) | VAF 36/301 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1335091608, COSV68405075; called by muse, mutect2, varscan2
- WIPI2 | c.257G>T p.S86I | Missense Mutation (SNP) | VAF 42/540 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56587667; called by muse, mutect2
- ZC3HAV1 | c.1325C>T p.T442I | Missense Mutation (SNP) | VAF 85/384 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV54293360; called by muse, mutect2, varscan2
- ZNF485 | c.629G>T p.R210M | Missense Mutation (SNP) | VAF 27/300 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs1161335375; called by muse, mutect2
- ZNF536 | c.1795G>T p.D599Y | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV62833857; called by muse, mutect2, varscan2
- ZNF679 | c.251C>T p.T84I | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55376770; called by muse, mutect2
- AC093791.1 | n.466-1G>A | Splice Site (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2, varscan2
- AC098582.1 | c.122G>T p.C41F | Missense Mutation (SNP) | VAF 43/417 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACSL4 | c.1060A>C p.K354Q (on ENST00000340800 / NM_022977.2; = p.K313Q on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADAMTS18 | c.190G>T p.V64F | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ADCY6 | c.1620_1636del p.Y541Hfs*2 | Frame Shift Del (DEL) | VAF 22/231 reads (10%) | called by mutect2, pindel
- ADCYAP1R1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 34/385 reads (9%) | called by muse, mutect2
- ALPK2 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 22/413 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.219); called by muse, mutect2
- ANK2 | c.4365T>A p.Y1455* | Nonsense Mutation (SNP) | VAF 40/545 reads (7%) | called by muse, mutect2
- APOB | c.9355G>T p.G3119* | Nonsense Mutation (SNP) | VAF 36/318 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 30/321 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- ARMCX4 | c.599T>A p.I200K (on ENST00000433011; = p.I96K on NM_001256155.2) | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- ASB12 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.142); called by muse, mutect2
- ASB18 | c.1102G>T p.V368L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ATP6V1G1 | c.26A>T p.Q9L | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- BIRC5 | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 39/233 reads (17%) | called by muse, mutect2, varscan2
- CCL11 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 41/481 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- CDK18 | c.542G>T p.G181V (on ENST00000506784 / NM_212503.3; = p.G151V on NM_002596.4) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDON | c.1201G>T p.G401C | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.011); called by muse, mutect2
- CEP76 | c.1745C>A p.A582D | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2
- CFAP69 | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- CFAP74 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- CHL1 | c.3337+1G>T p.X1113_splice (on ENST00000397491 / NM_001253387.1; = p.X1129_splice on NM_006614.4) | Splice Site (SNP) | VAF 23/125 reads (18%) | called by muse, mutect2, varscan2
- CLDN16 | c.612G>T p.R204S | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLPTM1L | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CMIP | c.437G>T p.S146I (on ENST00000537098 / NM_198390.2; = p.S52I on NM_030629.3) | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.258); called by muse, mutect2
- COQ5 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- CPN2 | c.520C>A p.L174I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CSH2 | c.382G>T p.V128L | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.022); called by muse, mutect2
- CUBN | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 51/550 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); called by muse, mutect2
- CWH43 | c.1748C>A p.T583N | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYP2B6 | c.626T>A p.I209N | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); called by muse, mutect2
- DCHS1 | c.1600G>T p.A534S | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.518); called by muse, mutect2
- DGKK | c.974T>A p.V325D | Missense Mutation (SNP) | VAF 94/378 reads (25%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- DHX40 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DKKL1 | c.634G>T p.V212F | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.21); called by muse, mutect2
- DLGAP3 | c.734A>T p.K245M | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- DNAH14 | c.8664G>T p.W2888C (on ENST00000445597; = p.W3691C on NM_001367479.1) | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNMT3L | c.346T>A p.C116S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ECH1 | c.321C>G p.I107M | Missense Mutation (SNP) | VAF 79/999 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, mutect2
- EDA | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- EPHB6 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ESRP2 | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2
- ETS2 | c.457G>T p.D153Y | Missense Mutation (SNP) | VAF 50/464 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EVA1A | c.320T>C p.L107S | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2
- FKRP | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FZD2 | c.1022G>T p.S341I | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- GABRA5 | c.1268G>T p.S423I | Missense Mutation (SNP) | VAF 24/536 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABRB3 | c.505C>A p.P169T | Missense Mutation (SNP) | VAF 58/722 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GATA3 | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 21/266 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.726); called by muse, mutect2
- GDF6 | c.1189C>A p.P397T | Missense Mutation (SNP) | VAF 48/488 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLDC | c.1483-2A>T p.X495_splice | Splice Site (SNP) | VAF 58/469 reads (12%) | called by muse, mutect2, varscan2
- GPR34 | c.1123C>A p.Q375K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, varscan2
- GPR85 | c.991del p.Q331Kfs*16 | Frame Shift Del (DEL) | VAF 42/280 reads (15%) | called by mutect2, pindel, varscan2
- GSG1L2 | c.430G>T p.G144C | Missense Mutation (SNP) | VAF 19/394 reads (5%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); called by muse, mutect2
- GUCY2F | c.1823C>A p.P608H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- HEPH | c.290del p.G97Afs*19 (on ENST00000343002; = p.G151Afs*19 on NM_138737.5) | Frame Shift Del (DEL) | VAF 26/287 reads (9%) | called by mutect2, pindel
- HLA-DRB1 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- IDE | c.1580A>T p.K527M | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- IGHM | c.829C>A p.H277N | Missense Mutation (SNP) | VAF 61/588 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- IGKV1D-17 | c.185C>A p.P62Q | Missense Mutation (SNP) | VAF 44/838 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2
- IL1RAP | c.782A>T p.E261V | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- IPO7 | c.1079A>G p.Y360C | Missense Mutation (SNP) | VAF 30/293 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ISLR2 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); called by muse, mutect2
- ITGA10 | c.1850G>T p.G617V | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- ITGA10 | c.1849G>T p.G617C | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- ITGAE | c.2560C>A p.L854M | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KIF18A | c.2479G>C p.A827P | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KIF4B | c.3283G>T p.G1095W | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); called by muse, varscan2
- KIRREL3 | c.1574C>A p.A525D | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.103); called by muse, mutect2
- KLHL9 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- KRT6B | c.1493G>T p.G498V | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- LILRA4 | c.480C>A p.H160Q | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- LRIT1 | c.1300G>T p.V434L | Missense Mutation (SNP) | VAF 23/269 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- MACC1 | c.1298T>A p.L433* | Nonsense Mutation (SNP) | VAF 27/200 reads (14%) | called by muse, mutect2, varscan2
- MAMLD1 | c.2045A>T p.H682L | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MOV10 | c.245G>T p.W82L | Missense Mutation (SNP) | VAF 42/717 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2
- MPO | c.355C>A p.L119M | Missense Mutation (SNP) | VAF 26/217 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MVK | c.906G>T p.Q302H | Missense Mutation (SNP) | VAF 19/229 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); called by muse, mutect2
- MYO3A | c.1662-1G>A p.X554_splice | Splice Site (SNP) | VAF 30/289 reads (10%) | called by muse, mutect2, varscan2
- NAV2 | c.4906T>A p.W1636R | Missense Mutation (SNP) | VAF 37/363 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV2 | c.4907G>T p.W1636L | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NCAM2 | c.1855G>T p.G619* | Nonsense Mutation (SNP) | VAF 35/300 reads (12%) | called by muse, mutect2
- NCOA2 | c.2485G>T p.A829S | Missense Mutation (SNP) | VAF 66/844 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- NEK1 | c.117+1G>C p.X39_splice | Splice Site (SNP) | VAF 20/267 reads (7%) | called by muse, mutect2
- NLRP3 | c.2680C>A p.L894I | Missense Mutation (SNP) | VAF 55/595 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); called by muse, mutect2
- NOS3 | c.2274G>T p.M758I | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, varscan2
- NRAP | c.4556G>T p.W1519L (on ENST00000359988 / NM_001322945.2; = p.W1484L on NM_006175.4) | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NUP214 | c.6185G>T p.G2062V | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2
- OBSCN | c.20335G>T p.A6779S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OOEP | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR2AK2 | c.484T>A p.Y162N | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- OR2M2 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 44/622 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2
- OR4D10 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PASK | c.1144A>T p.T382S | Missense Mutation (SNP) | VAF 33/301 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- PCDH11X | c.1442C>A p.P481H | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDHB1 | c.2096C>A p.S699Y | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- PCDHGA9 | c.2392A>T p.K798* | Nonsense Mutation (SNP) | VAF 48/468 reads (10%) | called by muse, mutect2
- PCNT | c.2120A>T p.Q707L | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- PDGFRA | c.2300C>A p.S767* | Nonsense Mutation (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- PDZRN3 | c.1561G>T p.D521Y | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX16 | c.289G>T p.E97* | Nonsense Mutation (SNP) | VAF 25/249 reads (10%) | called by muse, mutect2, varscan2
- PEX26 | c.259G>T p.V87F | Missense Mutation (SNP) | VAF 32/275 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PIK3C2G | c.2716G>A p.E906K (on ENST00000676171; = p.E865K on NM_004570.5) | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.392); called by muse, mutect2
- PLXNB3 | c.5409+3G>A | Splice Region (SNP) | VAF 34/230 reads (15%) | called by muse, mutect2, varscan2
- PLXNC1 | c.1793G>A p.C598Y | Missense Mutation (SNP) | VAF 30/298 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- POTEF | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 49/400 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- POU4F1 | c.49C>T p.L17F | Missense Mutation (SNP) | VAF 36/216 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R3F | c.1531G>T p.G511C | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); called by muse, mutect2
- PPP2R1B | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 35/658 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- PPP4R3C | c.1235G>C p.S412T | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2
- PRAMEF20 | c.802T>A p.C268S | Missense Mutation (SNP) | VAF 66/782 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.096); called by muse, mutect2
- PRAMEF4 | c.1244A>T p.Y415F | Missense Mutation (SNP) | VAF 82/647 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PRKCB | c.359C>A p.S120* | Nonsense Mutation (SNP) | VAF 32/326 reads (10%) | called by muse, mutect2, varscan2
- PRPF38B | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); called by muse, mutect2
- PTCHD3 | c.918G>T p.L306F | Missense Mutation (SNP) | VAF 33/247 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTPRD | c.4884C>G p.Y1628* | Nonsense Mutation (SNP) | VAF 24/234 reads (10%) | called by muse, mutect2, varscan2
- PTPRM | c.4305+1G>T p.X1435_splice | Splice Site (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- PUS10 | c.678-1G>T p.X226_splice | Splice Site (SNP) | VAF 55/516 reads (11%) | called by muse, mutect2, varscan2
- PYHIN1 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- RALGAPA1 | c.1449+1G>T p.X483_splice | Splice Site (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- RDX | c.951G>C p.Q317H | Missense Mutation (SNP) | VAF 30/648 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2
- RET | c.2872G>T p.E958* | Nonsense Mutation (SNP) | VAF 58/618 reads (9%) | called by muse, mutect2
- RGPD8 | c.2881A>T p.I961F | Missense Mutation (SNP) | VAF 95/1041 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RGPD8 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2
- RHBDF2 | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMS2 | c.2195C>A p.S732* (on ENST00000666250 / NM_001348490.2; = p.S540* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 26/148 reads (18%) | called by muse, mutect2, varscan2
- RIMS2 | c.3289C>A p.P1097T (on ENST00000666250 / NM_001348490.2; = p.P905T on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/505 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASE12 | c.230dup p.N77Kfs*24 | Frame Shift Ins (INS) | VAF 51/458 reads (11%) | called by mutect2, pindel, varscan2
- RSPO3 | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 24/464 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.968); called by muse, mutect2
- SCRIB | c.2679C>A p.F893L | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC2A14 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.014); called by muse, mutect2
- SLC35E2B | c.865A>T p.S289C | Missense Mutation (SNP) | VAF 34/706 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.721); called by muse, mutect2
- SMYD5 | c.1018G>T p.D340Y | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SOHLH1 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 18/248 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- SORL1 | c.6212C>T p.T2071I | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2
- SP110 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); called by muse, mutect2
- SPATA31D1 | c.2800G>T p.D934Y | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.331); called by muse, mutect2
- SPHKAP | c.3571A>T p.T1191S | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SPP1 | c.213del p.E72Rfs*40 | Frame Shift Del (DEL) | VAF 32/326 reads (10%) | called by mutect2, pindel, varscan2
- SRCAP | c.6975G>T p.E2325D | Missense Mutation (SNP) | VAF 36/304 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- SSU72P8 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- STARD6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 39/380 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- STK31 | c.167A>T p.K56M | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, varscan2
- STYXL2 | c.163C>A p.H55N | Missense Mutation (SNP) | VAF 27/452 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- TAZ | c.239-7C>T | Splice Region (SNP) | VAF 46/398 reads (12%) | called by muse, mutect2, varscan2
- TBX15 | c.1199C>T p.P400L (on ENST00000369429 / NM_001330677.2; = p.P294L on NM_152380.3) | Missense Mutation (SNP) | VAF 34/625 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2
- TGM7 | c.1763C>A p.A588E | Missense Mutation (SNP) | VAF 25/337 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2
- TMPRSS4 | c.1240A>T p.S414C | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2
- TNRC6C | c.4037G>T p.R1346L | Missense Mutation (SNP) | VAF 56/334 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- TRIM66 | c.3502A>G p.S1168G | Missense Mutation (SNP) | VAF 42/400 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSR2 | c.305G>T p.R102M | Missense Mutation (SNP) | VAF 19/253 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2
- TTC34 | c.1612C>A p.P538T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- U2AF2 | c.1321G>C p.D441H | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2
- UNC5C | c.1094G>T p.G365V | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC80 | c.6619C>A p.L2207I | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- WBP11 | c.479G>T p.G160V | Missense Mutation (SNP) | VAF 43/443 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZFHX4 | c.4883C>A p.P1628H | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- ZIM2 | c.824A>T p.K275M | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ZMYM4 | c.1538G>T p.C513F | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- ZNF197 | c.2884G>C p.D962H | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); called by muse, mutect2
- ZNF415 | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZNF423 | c.3628C>A p.L1210M (on ENST00000563137 / NM_001379286.1; = p.L1202M on NM_015069.4) | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF543 | c.1148T>A p.I383N | Missense Mutation (SNP) | VAF 43/449 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF644 | c.1750G>T p.A584S | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- ZNF711 | c.175G>T p.G59W | Missense Mutation (SNP) | VAF 37/380 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2
- ZNF735 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 42/447 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2
- ZSWIM9 | c.106G>T p.A36S | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.105); called by muse, mutect2
- ABCB1 | c.2598C>G p.P866= | Silent (SNP) | VAF 59/547 reads (11%) | called by muse, mutect2, varscan2
- ACSM4 | c.522G>T p.A174= | Silent (SNP) | VAF 78/608 reads (13%) | called by muse, mutect2, varscan2
- AFAP1L2 | c.1899G>A p.V633= | Silent (SNP) | VAF 27/336 reads (8%) | called by muse, mutect2
- ALX1 | c.957C>A p.T319= | Silent (SNP) | VAF 36/383 reads (9%) | catalogued as COSV57491786, COSV57492076; called by muse, mutect2
- ANK2 | c.5421A>T p.P1807= | Silent (SNP) | VAF 8/101 reads (8%) | called by muse, mutect2
- ANKRD34A | c.1386C>A p.P462= | Silent (SNP) | VAF 7/156 reads (4%) | called by muse, mutect2
- ARMCX4 | c.597C>A p.A199= (on ENST00000433011; = p.A95= on NM_001256155.2) | Silent (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- BIRC6 | c.14325G>T p.A4775= | Silent (SNP) | VAF 24/448 reads (5%) | catalogued as rs773960842; called by muse, mutect2
- C9orf50 | c.792C>A p.P264= | Silent (SNP) | VAF 19/127 reads (15%) | called by muse, mutect2, varscan2
- CACNA1B | c.4191G>T p.V1397= | Silent (SNP) | VAF 37/572 reads (6%) | catalogued as COSV53116967; called by muse, mutect2
- CACNA2D1 | c.817C>A p.R273= | Silent (SNP) | VAF 41/558 reads (7%) | catalogued as rs754162606, COSV100667634, COSV62379116; called by muse, mutect2
- CAMTA1 | c.645C>A p.I215= | Silent (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- CD22 | c.2064G>T p.V688= | Silent (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2, varscan2
- CIC | c.2922C>T p.P974= | Silent (SNP) | VAF 43/371 reads (12%) | catalogued as rs1476730356; called by muse, mutect2, varscan2
- COL11A1 | c.3582T>C p.P1194= | Silent (SNP) | VAF 13/391 reads (3%) | called by muse, mutect2
- CPED1 | c.2427C>A p.V809= | Silent (SNP) | VAF 126/568 reads (22%) | catalogued as COSV60008934; called by muse, mutect2, varscan2
- DCDC1 | c.4221A>T p.T1407= (on ENST00000597505 / NM_001367979.1; = p.T514= on NM_020869.3) | Silent (SNP) | VAF 19/471 reads (4%) | called by muse, mutect2
- DENND1B | c.162C>T p.P54= | Silent (SNP) | VAF 54/338 reads (16%) | called by muse, mutect2, varscan2
- DNAI3 | c.852C>A p.S284= | Silent (SNP) | VAF 23/149 reads (15%) | called by muse, mutect2, varscan2
- DTHD1 | c.216G>T p.L72= (on ENST00000456874; = p.L197= on NM_001170700.3) | Silent (SNP) | VAF 30/424 reads (7%) | called by muse, mutect2
- DZIP1 | c.2493C>A p.G831= (on ENST00000347108; = p.G812= on NM_014934.5) | Silent (SNP) | VAF 24/144 reads (17%) | catalogued as COSV61267065; called by muse, mutect2, varscan2
- ELMO2 | c.180C>T p.Y60= | Silent (SNP) | VAF 39/295 reads (13%) | catalogued as rs1206626715; called by muse, mutect2, varscan2
- FAM83F | c.1245C>A p.S415= | Silent (SNP) | VAF 20/176 reads (11%) | catalogued as COSV60999976; called by muse, mutect2, varscan2
- FBLIM1 | c.685C>A p.R229= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs772093436, COSV60030960, COSV60031768; called by muse, mutect2, varscan2
- FLG2 | c.744G>T p.G248= | Silent (SNP) | VAF 47/357 reads (13%) | called by muse, mutect2, varscan2
- GDI1 | c.654G>T p.R218= | Silent (SNP) | VAF 26/429 reads (6%) | called by muse, mutect2
- GRM3 | c.579C>A p.P193= | Silent (SNP) | VAF 35/315 reads (11%) | catalogued as COSV100862996, COSV64470865; called by muse, mutect2, varscan2
- GTF2A1 | c.960G>T p.V320= | Silent (SNP) | VAF 27/359 reads (8%) | called by muse, mutect2
- HAUS1 | c.597A>T p.A199= | Silent (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- HSPA12A | c.739C>A p.R247= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- IYD | c.24G>A p.L8= | Silent (SNP) | VAF 31/614 reads (5%) | called by muse, mutect2
- JAKMIP3 | c.1944G>T p.V648= | Silent (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2, varscan2
- KCNJ1 | c.1005G>T p.G335= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV60661855, COSV60661881; called by muse, mutect2, varscan2
- MACC1 | c.990A>G p.K330= | Silent (SNP) | VAF 18/177 reads (10%) | called by muse, mutect2, varscan2
- MGAM | c.3927G>A p.G1309= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV72075721; called by muse, mutect2, varscan2
- MGAM | c.4587C>A p.A1529= | Silent (SNP) | VAF 80/300 reads (27%) | called by muse, mutect2, varscan2
- MTRNR2L10 | c.67C>A p.R23= | Silent (SNP) | VAF 24/227 reads (11%) | called by muse, mutect2, varscan2
- OR1D2 | c.12C>A p.G4= | Silent (SNP) | VAF 18/134 reads (13%) | called by muse, mutect2
- OR2T4 | c.108C>A p.A36= | Silent (SNP) | VAF 48/535 reads (9%) | called by muse, mutect2
- OR5D16 | c.792C>A p.P264= | Silent (SNP) | VAF 29/350 reads (8%) | called by muse, mutect2
- OSBPL10 | c.987G>A p.Q329= | Silent (SNP) | VAF 31/255 reads (12%) | called by muse, mutect2, varscan2
- OVCH1 | c.1206C>A p.G402= | Silent (SNP) | VAF 35/445 reads (8%) | called by muse, mutect2
- PELP1 | c.804G>T p.L268= | Silent (SNP) | VAF 40/330 reads (12%) | called by muse, mutect2, varscan2
- PON3 | c.816C>T p.V272= | Silent (SNP) | VAF 41/535 reads (8%) | catalogued as rs145245780; called by muse, mutect2
- PRDX6 | c.135A>G p.P45= | Silent (SNP) | VAF 50/490 reads (10%) | catalogued as rs749163040; called by muse, mutect2, varscan2
- PXDNL | c.3402C>T p.A1134= | Silent (SNP) | VAF 53/298 reads (18%) | catalogued as rs749277291, COSV62480434; called by muse, varscan2
- RIMBP2 | c.55C>T p.L19= | Silent (SNP) | VAF 11/124 reads (9%) | called by muse, mutect2
- RIPOR3 | c.775C>T p.L259= | Silent (SNP) | VAF 18/106 reads (17%) | called by mutect2, varscan2
- RTL1 | c.2790C>A p.A930= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SCOC | c.117G>A p.L39= | Silent (SNP) | VAF 16/189 reads (8%) | called by muse, mutect2
- SENP7 | c.1437A>C p.A479= | Silent (SNP) | VAF 23/393 reads (6%) | called by muse, mutect2
- SLC26A7 | c.675T>G p.S225= | Silent (SNP) | VAF 52/205 reads (25%) | called by muse, mutect2, varscan2
- SV2A | c.1983C>A p.V661= | Silent (SNP) | VAF 93/519 reads (18%) | called by muse, mutect2, varscan2
- TNN | c.642C>T p.R214= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs976390531; called by muse, mutect2, varscan2
- TOMM70 | c.210C>T p.G70= | Silent (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- TXLNB | c.1674C>A p.P558= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV64444387; called by muse, mutect2
- UNC80 | c.7368A>T p.G2456= | Silent (SNP) | VAF 27/275 reads (10%) | called by muse, mutect2
- USP51 | c.1908C>A p.G636= | Silent (SNP) | VAF 42/434 reads (10%) | called by muse, mutect2
- AC005865.1 | n.1696C>A | RNA (SNP) | VAF 22/202 reads (11%) | called by muse, varscan2
- ACAP3 | c.738+36G>T | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as rs968313817; called by muse, mutect2, varscan2
- ACTN2 | c.-20G>T | 5'UTR (SNP) | VAF 15/158 reads (9%) | called by muse, mutect2
- ANAPC1P4 | n.1792C>T | RNA (SNP) | VAF 49/495 reads (10%) | called by muse, mutect2, varscan2
- ARID4B | c.3448+937C>T | Intron (SNP) | VAF 36/372 reads (10%) | called by muse, mutect2
- AVPR2 | chrX:153902708 G>T | 5'Flank (SNP) | VAF 9/216 reads (4%) | called by muse, mutect2
- C1orf229 | n.503G>A | RNA (SNP) | VAF 11/96 reads (11%) | catalogued as rs764980570; called by muse, mutect2, varscan2
- CCDC179 | c.*6C>A | 3'UTR (SNP) | VAF 15/324 reads (5%) | called by muse, mutect2
- CCDC65 | c.-2C>A | 5'UTR (SNP) | VAF 10/124 reads (8%) | catalogued as COSV99907923; called by muse, mutect2
- CDH3 | c.*2C>A | 3'UTR (SNP) | VAF 8/62 reads (13%) | called by muse, varscan2
- CFAP47 | c.5536-451A>T | Intron (SNP) | VAF 52/213 reads (24%) | called by muse, mutect2, varscan2
- COL9A2 | c.75+455G>A | Intron (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- CTBP2 | c.58+12732G>T | Intron (SNP) | VAF 16/230 reads (7%) | called by muse, mutect2
- DISC1 | c.2307+102T>A | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- DROSHA | c.*37G>T | 3'UTR (SNP) | VAF 53/401 reads (13%) | called by muse, mutect2, varscan2
- FAM53C | chr5:138337981 G>T | 5'Flank (SNP) | VAF 49/478 reads (10%) | called by muse, mutect2, varscan2
- FAM78B | c.263+11232C>T | Intron (SNP) | VAF 32/329 reads (10%) | called by muse, mutect2
- GABRG3 | c.1123-1891C>A | Intron (SNP) | VAF 23/198 reads (12%) | called by muse, mutect2, varscan2
- HMGA2 | c.*29G>T | 3'UTR (SNP) | VAF 39/554 reads (7%) | called by muse, mutect2
- HNRNPU | c.634+39_634+61del | Intron (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- IGHV1-24 | c.-4C>G | 5'UTR (SNP) | VAF 18/201 reads (9%) | called by muse, mutect2
- KIF17 | c.2020-145del | Intron (DEL) | VAF 30/295 reads (10%) | called by mutect2, pindel, varscan2
- LGR5 | c.-64G>T | 5'UTR (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- MGP | c.95-39G>T | Intron (SNP) | VAF 58/357 reads (16%) | called by muse, mutect2, varscan2
- MIR183 | n.30G>T | RNA (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- MIR365A | n.28G>A | RNA (SNP) | VAF 67/532 reads (13%) | called by muse, mutect2, varscan2
- MIR9-1HG | n.456+177A>T | Intron (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- NELL1 | c.56-3407G>T | Intron (SNP) | VAF 48/386 reads (12%) | called by muse, mutect2, varscan2
- NELL1 | c.56-3406G>T | Intron (SNP) | VAF 47/385 reads (12%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.639G>C | RNA (SNP) | VAF 14/317 reads (4%) | called by muse, mutect2
- OFD1 | c.1056-621A>T | Intron (SNP) | VAF 24/463 reads (5%) | called by muse, mutect2
- OR2W5 | n.961C>A | RNA (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- OR6W1P | n.114G>T | RNA (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- POLM | c.714+15G>T | Intron (SNP) | VAF 21/181 reads (12%) | catalogued as rs921085339; called by muse, mutect2, varscan2
- PRMT5 | c.*174G>T | 3'UTR (SNP) | VAF 31/302 reads (10%) | called by muse, mutect2, varscan2
- RAD51B | c.*6dup | 3'UTR (INS) | VAF 18/171 reads (11%) | called by mutect2, pindel
- RGS8 | c.-13A>T | 5'UTR (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159111 G>T | 5'Flank (SNP) | VAF 8/175 reads (5%) | called by muse, mutect2
- ROBO2 | c.1850-27G>T | Intron (SNP) | VAF 37/321 reads (12%) | catalogued as rs758318018; called by muse, mutect2, varscan2
- RPL31P57 | n.197C>A | RNA (SNP) | VAF 23/231 reads (10%) | called by muse, mutect2, varscan2
- RXRA | n.316G>T | RNA (SNP) | VAF 19/162 reads (12%) | called by muse, mutect2, varscan2
- SCN4B | c.*2360C>T | 3'UTR (SNP) | VAF 49/402 reads (12%) | called by muse, mutect2, varscan2
- SLC22A25 | c.507-2226C>A | Intron (SNP) | VAF 37/356 reads (10%) | called by muse, mutect2, varscan2
- SNORD115-26 | n.36G>T | RNA (SNP) | VAF 44/454 reads (10%) | called by muse, mutect2
- SORBS2 | c.684+7653G>T | Intron (SNP) | VAF 10/208 reads (5%) | catalogued as COSV52994797; called by muse, mutect2
- SPTA1 | c.6788+51G>T | Intron (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- STAT1 | c.-1-407C>T | Intron (SNP) | VAF 18/277 reads (6%) | catalogued as rs1459026520; called by muse, mutect2
- TAL1 | c.*134C>A | 3'UTR (SNP) | VAF 55/409 reads (13%) | catalogued as COSV53748245; called by muse, mutect2, varscan2
- TRAV2 | c.-3G>T | 5'UTR (SNP) | VAF 20/169 reads (12%) | called by muse, mutect2, varscan2
- TTC19 | c.*1171G>T | 3'UTR (SNP) | VAF 32/271 reads (12%) | called by muse, mutect2, varscan2
- UBBP4 | n.604G>A | RNA (SNP) | VAF 80/531 reads (15%) | called by muse, mutect2, varscan2
- UBTFL2 | n.741T>A | RNA (SNP) | VAF 43/1000 reads (4%) | called by muse, mutect2
- UNC13C | c.4933+1842G>T | Intron (SNP) | VAF 16/268 reads (6%) | catalogued as COSV52907777; called by muse, mutect2
- USH1C | c.1285-3905T>A | Intron (SNP) | VAF 59/426 reads (14%) | called by muse, mutect2, varscan2
- WASF4P | n.845G>C | RNA (SNP) | VAF 18/339 reads (5%) | called by muse, mutect2
- WT1 | chr11:32438920 G>T | 5'Flank (SNP) | VAF 22/155 reads (14%) | catalogued as rs558752929; called by muse, mutect2, varscan2
- ZEB2 | chr2:144520174 C>A | 5'Flank (SNP) | VAF 66/941 reads (7%) | called by muse, mutect2
